Gene-level copy-number profile of tumor specimen HTMCP-01-06-00611-01A from CGCI case HTMCP-01-06-00611, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.5 years (25,028 days).
Specimen HTMCP-01-06-00611-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5ffb5fd6-2f5e-42f8-996c-852c0e719843.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00611-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/d18b565d-0f3d-4640-9389-b528c8395e5b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 4,959; copy number 2: 48,141; copy number 3: 5,755; copy number 4: 7.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 37 genes (within-gene range 0–2): IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr17:46,274,784–46,579,691, 9 genes: ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
